Gene-level copy-number profile of tumor specimen TCGA-14-1402-01A from TCGA case TCGA-14-1402, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.6 years (21,421 days).
Specimen TCGA-14-1402-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.f382c62d-ac85-4dbb-9257-e19805082146.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-1402-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2211cddc-a7c6-4d7c-8feb-f797f1097612

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 1; copy number 2: 4,243; copy number 3: 21; copy number 4: 50,013; copy number 5: 500; copy number 6: 4,640; copy number 7: 3; copy number 14: 96; copy number 15: 174; copy number 16: 11; copy number 17: 62; copy number 52: 7; copy number 65: 24; copy number 68: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-14-1402-01): tumor purity 0.79, ploidy 2, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,214,672, 9 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 382 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:44,064,908–44,849,568, 27 genes, copy number 15: AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2, NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC004938.2, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952.
- chr7:48,171,458–48,647,497, 1 gene, copy number 17 (within-gene range 6–17): ABCA13.
- chr7:54,185,071–55,713,252, 30 genes, copy number 16–65: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.
- chr7:56,597,379–57,837,046, 78 genes, copy number 14–52 (broad region; genes not listed).
- chr7:65,038,354–67,239,519, 74 genes, copy number 14 (broad region; genes not listed).
- chr7:75,769,533–75,986,855, 8 genes, copy number 68 (within-gene range 4–68): CCL26, CCL24, AC005102.1, RHBDD2, POR, MIR4651, RPL7L1P3, SNORA14A.
- chr7:92,112,153–94,834,447, 59 genes, copy number 17: CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2, AC002074.1, AC002074.2, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1.
- chr7:95,018,163–95,018,554, 2 genes, copy number 17: HINT1P2, AC002429.1.
- chr7:99,869,841–101,252,316, 103 genes, copy number 15–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
